Gene-level copy-number profile of tumor specimen ALCH-AFAD-TTP1-A from ALCHEMIST case ALCH-AFAD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.6 years (26,146 days).
Specimen ALCH-AFAD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 432c4f3a-f756-4e37-a18c-2b8f0787b7f4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFAD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/41af1074-19db-4bd9-875b-a6616d4d077d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 979; copy number 1: 15,515; copy number 2: 34,365; copy number 3: 5,894; copy number 4: 1,641; copy number 5: 302; copy number 6: 98; copy number 7: 5; copy number 9: 5; copy number 12: 2; copy number 17: 18; copy number 21: 2; copy number 29: 17; copy number 31: 15; copy number 32: 21; copy number 34: 5; copy number 47: 17.

Homozygous deletions (total copy number 0; autosomes only): 413 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,567,910–12,619,244, 4 genes: DHRS3, RNU6ATAC18P, MIR6730, AC254633.1.
- chr1:12,716,110–13,516,270, 43 genes: AADACL3, C1orf158, PRAMEF12, PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10, PRAMEF7, RNU6-1072P, PRAMEF29P, PRAMEF6, PRAMEF28P, PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF34P, PRAMEF35P, HNRNPCL2, PRAMEF36P, AC245056.1, PRAMEF26, HNRNPCL4, PRAMEF9, PRAMEF13, PRAMEF18, PRAMEF31P, PRAMEF5, PRAMEF32P, RNU6-771P, PRAMEF8, PRAMEF33, PRAMEF15, AC243961.1, PRAMEF14, PRAMEF19, PRAMEF17, PRAMEF20, LRRC38, AL354712.1.
- chr1:20,719,731–20,733,952, 2 genes: SH2D5, AL663074.1.
- chr3:88,601,061–88,601,402, 1 gene: NDUFA5P5.
- chr4:164,597,719–164,620,837, 2 genes: AC074198.1, RNU6-284P.
- chr4:188,091,273–188,147,743, 5 genes: TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1.
- chr7:75,769,533–75,789,896, 1 gene: CCL26.
- chr7:101,362,875–101,559,024, 2 genes (within-gene range 0–1): COL26A1, AC004965.1.
- chr7:139,448,740–139,448,843, 1 gene: RNU6-911P.
- chr7:140,435,316–140,673,993, 5 genes (within-gene range 0–2): AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1.
- chr8:22,042,398–22,048,809, 1 gene: FGF17.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr9:123,402,525–123,493,156, 3 genes (within-gene range 0–1): MIR601, MIR7150, AL445489.1.
- chr9:137,838,419–138,253,217, 9 genes (within-gene range 0–2): MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr11:70,467,856–71,252,577, 10 genes (within-gene range 0–2): SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr13:111,316,184–111,344,249, 1 gene: TEX29.
- chr15:19,878,555–23,630,075, 169 genes (broad region; genes not listed).
- chr15:25,169,337–25,257,027, 46 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:64,701,248–64,825,668, 4 genes (within-gene range 0–2): AC100830.1, RBPMS2, MIR1272, PIF1.
- chr16:89,906,157–90,222,851, 20 genes (within-gene range 0–1): AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.
- chr17:3,672,199–3,801,188, 5 genes (within-gene range 0–1): P2RX5, ITGAE, AC116914.2, HASPIN, AC116914.1.
- chr17:4,433,940–4,488,208, 2 genes: SPNS3, AC127521.1.
- chr17:31,533,171–31,534,971, 2 genes (within-gene range 0–2): AC003101.3, MIR4724.
- chr18:37,273,706–37,306,333, 2 genes (within-gene range 0–2): AC090386.1, AC090386.2.
- chr18:79,902,420–79,970,822, 2 genes (within-gene range 0–1): SLC66A2, HSBP1L1.
- chr19:7,348,943–7,561,764, 12 genes: AC119396.1, AC008878.3, AC119396.2, ARHGEF18, PEX11G, TEX45, AC008878.1, ZNF358, AC008878.4, MCOLN1, AC008878.2, PNPLA6.
- chr19:9,959,561–10,022,279, 3 genes: COL5A3, AC008742.1, RDH8.
- chr19:15,221,015–15,222,297, 1 gene: AC004257.1.
- chr19:19,668,796–19,754,986, 7 genes: ZNF101, AC011458.2, AC011458.1, ZNF14, AC011477.6, AC011477.7, AC011477.5.
- chr19:53,787,597–53,990,215, 14 genes: AC008753.3, MIR371A, MIR371B, MIR372, MIR373, AC008753.2, NLRP12, MYADM-AS1, MYADM, AC008440.1, PRKCG, CACNG7, CACNG8, MIR935.
- chr19:56,127,236–56,217,777, 7 genes: AC024580.2, ZNF444, AC024580.1, GALP, ZSCAN5B, ZSCAN5C, AC011506.1.
- chr19:56,244,043–56,247,482, 1 gene (within-gene range 0–1): ZSCAN5DP.
- chr20:316,860–359,660, 3 genes: NRSN2-AS1, SOX12, NRSN2.
- chr21:36,319,792–36,419,015, 5 genes: AP000692.2, MORC3, AP000692.1, CHAF1B, ATP5MFP1.
- chr22:41,174,591–41,399,326, 10 genes (within-gene range 0–1): EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889, ZC3H7B, TEF, RNU6-495P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 507 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,166,932–1,208,962, 1 gene, copy number 5 (within-gene range 2–5): SPON2.
- chr4:1,211,445–1,249,953, 1 gene, copy number 5 (within-gene range 2–5): CTBP1.
- chr6:40,713,411–44,553,281, 144 genes, copy number 5 (broad region; genes not listed).
- chr7:155,611,231–155,781,485, 2 genes, copy number 5: AC009403.1, RBM33.
- chr8:128,150,116–128,220,803, 2 genes, copy number 7: MIR1208, RN7SKP226.
- chr8:140,657,900–144,063,965, 121 genes, copy number 5–6 (broad region; genes not listed).
- chr9:136,807,943–136,841,187, 1 gene, copy number 5 (within-gene range 4–5): RABL6.
- chr9:136,862,119–136,993,984, 13 genes, copy number 5–6 (within-gene range 5–13): EDF1, TRAF2, MIR4479, AL807752.1, AL807752.5, FBXW5, C8G, LCN12, LINC02692, PTGDS, AL807752.7, LCNL1, PAXX.
- chr9:137,031,241–137,070,557, 7 genes, copy number 5–6 (within-gene range 3–6): AL807752.6, NPDC1, ENTPD2, AL807752.4, AL807752.2, SAPCD2, AL807752.3.
- chr9:137,220,247–137,236,555, 4 genes, copy number 6: RNF208, CYSRT1, RNF224, SLC34A3.
- chr9:137,293,868–137,302,271, 3 genes, copy number 5: BX255925.1, BX255925.4, NRARP.
- chr10:28,050,993–28,334,486, 2 genes, copy number 5 (within-gene range 3–5): MPP7, AL355501.1.
- chr10:28,303,300–28,307,658, 1 gene, copy number 5: MPP7-DT.
- chr12:23,529,504–28,581,511, 97 genes, copy number 12–47 (broad region; genes not listed).
- chr12:127,758,832–127,898,645, 4 genes, copy number 5: AC087894.3, AC087894.2, AC087894.1, LINC02393.
- chr14:35,511,825–37,172,606, 36 genes, copy number 6 (within-gene range 3–6): KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503.
- chr18:47,105,946–47,630,848, 12 genes, copy number 6: AC012254.3, HDHD2, AC012254.2, AC012254.4, IER3IP1, SKOR2, RNU6-1131P, MIR4527HG, MIR4527, AC102797.2, AC102797.1, TPMTP1.
- chr18:47,808,957–47,931,146, 5 genes, copy number 9 (within-gene range 9–10): SMAD2, MTCO2P2, AC120349.3, AC120349.1, AC120349.2.
- chr18:48,539,031–49,742,063, 32 genes, copy number 6: CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1, AC090227.3.
- chr19:984,332–1,106,791, 12 genes, copy number 5–6: WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4.
- chr19:1,383,527–1,396,467, 3 genes, copy number 7: NDUFS7, AC005329.3, AC005329.1.
- chr21:32,628,759–32,771,792, 3 genes, copy number 5: SYNJ1, PAXBP1-AS1, PAXBP1.
- chr21:45,234,308–45,264,548, 1 gene, copy number 5 (within-gene range 2–5): LINC00334.

Autosomal genes at a single copy (total copy number 1): 13,225. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
